Somatic mutation profile of tumor specimen TCGA-60-2715-01A (aliquot TCGA-60-2715-01A-01D-1522-08) from TCGA case TCGA-60-2715, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.0 years (18,990 days).
Specimen TCGA-60-2715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce3a8769-fa07-421b-89b6-2f27d3769545.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2715-11A (Solid Tissue Normal), aliquot TCGA-60-2715-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bdbdbb4-a8c7-44d1-8d49-3e3c6759c20d

The open-access MAF lists 125 somatic variants for this specimen: 93 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 29, Nonsense Mutation 11, Frame Shift Del 2, RNA 1, Splice Site 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A2 | c.3110G>A p.G1037E | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs387906603, CM120247, COSV64635437; ClinVar: pathogenic; called by muse, mutect2
- KCNH2 | c.1913A>G p.K638R | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs794728378, COSV51239018; ClinVar: pathogenic; called by muse, mutect2
- ABCB1 | c.1301G>T p.S434I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747479750, COSV55965448; called by muse, varscan2
- ABCB4 | c.2044G>T p.D682Y | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs1488247315, COSV55942871; called by muse, mutect2
- ALG2 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs780287266, COSV53061085; called by muse, mutect2
- ATP10A | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs750431834, COSV63520534; called by muse, mutect2, varscan2
- ATP6V0A2 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57752806; called by muse, mutect2, varscan2
- ATXN2L | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1434041581, COSV57380189; called by muse, mutect2, varscan2
- BAG5 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 15/220 reads (7%) | catalogued as COSV54572963; called by muse, mutect2
- C6 | c.655A>G p.K219E | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.013); catalogued as COSV54720480; called by muse, mutect2, varscan2
- CACNA1C | c.4690G>T p.A1564S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV59780831; called by muse, mutect2
- CAD | c.1940T>C p.L647P | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV53032739; called by muse, mutect2, varscan2
- CARD10 | c.2595C>A p.D865E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV52660739; called by muse, mutect2, varscan2
- CCDC39 | c.798C>G p.I266M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); catalogued as COSV56495199, COSV99871024; called by muse, mutect2, varscan2
- CDHR5 | c.1852C>T p.Q618* (on ENST00000358353 / NM_001171968.2; = p.Q624* on NM_021924.5) | Nonsense Mutation (SNP) | VAF 12/194 reads (6%) | catalogued as COSV57646573; called by muse, mutect2
- CEP104 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV65511847, COSV65512979; called by muse, mutect2
- CEP128 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53679173; called by muse, mutect2
- CHRNB2 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63809627; called by muse, mutect2
- COL4A3 | c.1601C>A p.P534Q | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.499); catalogued as COSV101170544, COSV67421317; called by muse, mutect2
- CRYBB1 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV53234989; called by muse, mutect2, varscan2
- DAAM2 | c.2464G>C p.V822L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.124); catalogued as COSV51421612; called by muse, mutect2, varscan2
- DOCK4 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1035650705, COSV70237443; called by muse, mutect2
- DROSHA | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs151137891, COSV60783878; called by muse, mutect2
- DUS1L | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as rs1473468840, COSV57651789; called by muse, mutect2
- EBF2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746363034, COSV68779176; called by muse, mutect2
- EME1 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV56812652, COSV56813424; called by muse, mutect2
- EPRS1 | c.3833G>T p.R1278L | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100859333, COSV65101952; called by muse, mutect2
- ERV3-1 | c.374A>C p.Q125P | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99275370; called by muse, mutect2, varscan2
- FAT1 | c.8680G>T p.E2894* | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | catalogued as COSV71671959, COSV71676267; called by muse, mutect2, varscan2
- FIP1L1 | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61000325; called by muse, mutect2
- GGT7 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV60539613, COSV60543155; called by muse, mutect2, varscan2
- GLT1D1 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 81/422 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV55889353; called by muse, mutect2, varscan2
- GPATCH4 | c.849T>A p.N283K | Missense Mutation (SNP) | VAF 154/681 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58041759; called by muse, mutect2, varscan2
- GREB1 | c.4580A>T p.E1527V | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52197893; called by muse, mutect2, varscan2
- GSPT2 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61215391; called by muse, mutect2, varscan2
- GTPBP4 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 26/569 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs149028639, COSV62552452; called by muse, mutect2
- H2BC12 | c.34A>T p.K12* | Nonsense Mutation (SNP) | VAF 14/234 reads (6%) | catalogued as COSV63617800; called by muse, mutect2
- HAPLN1 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as COSV57152574; called by muse, mutect2
- HTR3C | c.1309T>A p.S437T | Missense Mutation (SNP) | VAF 66/721 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV59177688; called by muse, mutect2
- IKZF3 | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV53108008; called by muse, mutect2
- IL1RL2 | c.1324G>C p.V442L | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.153); catalogued as COSV51815894, COSV51819753; called by muse, mutect2, varscan2
- KCNV2 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV66055457, COSV66057704; called by muse, mutect2, varscan2
- KLHL1 | c.990G>T p.M330I | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV100918030, COSV64786204; called by muse, mutect2
- KRTAP5-6 | c.249T>A p.C83* | Nonsense Mutation (SNP) | VAF 28/185 reads (15%) | catalogued as COSV66289387, COSV66289429; called by muse, mutect2, varscan2
- KRTAP9-8 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV54201167; called by muse, mutect2
- LRRC2 | c.508A>T p.K170* | Nonsense Mutation (SNP) | VAF 18/287 reads (6%) | catalogued as COSV56129254; called by muse, mutect2
- LRRC7 | c.1271C>T p.S424L (on ENST00000651989 / NM_001370785.2; = p.S391L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV50650175; called by muse, mutect2
- LRRN3 | c.1286C>G p.P429R | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57824730; called by muse, mutect2, varscan2
- MANEA | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV62590772; called by muse, mutect2
- MKI67 | c.8495A>C p.E2832A | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV64077516; called by muse, mutect2, varscan2
- MYCBP2 | c.4147G>C p.E1383Q (on ENST00000357337; = p.E1421Q on NM_015057.5) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.146); catalogued as COSV62042292; called by muse, mutect2
- NCAN | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373921518, COSV53058525; called by muse, mutect2
- NCAN | c.2587G>T p.V863L | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV53060586; called by muse, mutect2
- NFAT5 | c.4009C>T p.Q1337* | Nonsense Mutation (SNP) | VAF 18/213 reads (8%) | catalogued as COSV63033599; called by muse, mutect2
- OR2B11 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1482456884, COSV59511623, COSV59511767, COSV59511827; called by muse, mutect2, varscan2
- OR52N1 | c.452T>G p.F151C | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs866085693, COSV57694137; called by muse, mutect2, varscan2
- PCDH17 | c.1788G>T p.Q596H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV64980373; called by muse, mutect2, varscan2
- PDE1C | c.1447G>T p.V483F | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV58531655; called by muse, mutect2, varscan2
- PHF1 | c.547A>G p.N183D | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV65703477; called by muse, mutect2, varscan2
- PPP1R3A | c.2309A>T p.E770V | Missense Mutation (SNP) | VAF 15/309 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52894528; called by muse, mutect2
- PTPRD | c.352+1G>A p.X118_splice | Splice Site (SNP) | VAF 33/273 reads (12%) | catalogued as COSV61987174; called by muse, mutect2, varscan2
- PYGM | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 18/262 reads (7%) | catalogued as COSV51231458; called by muse, mutect2
- RNF180 | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV56963388, COSV56965885; called by muse, mutect2, varscan2
- RP1 | c.1348C>G p.P450A | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55128694; called by muse, mutect2, varscan2
- RXFP3 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752173438, COSV57508245; called by muse, mutect2
- RYR2 | c.9619A>T p.N3207Y | Missense Mutation (SNP) | VAF 78/396 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63719414; called by muse, mutect2, varscan2
- SAP30BP | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758845704, COSV53130608; called by muse, mutect2
- SENP5 | c.1960C>T p.L654F | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.939); catalogued as COSV60210909; called by muse, mutect2, varscan2
- SNPH | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as COSV60591370; called by muse, mutect2
- SPTA1 | c.653A>C p.N218T | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63760952; called by muse, mutect2, varscan2
- SRCIN1 | c.3088C>T p.R1030C (on ENST00000621492; = p.R996C on NM_025248.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763311250; called by muse, mutect2, varscan2
- SYNE1 | c.12315A>C p.K4105N (on ENST00000367255 / NM_182961.4; = p.K4034N on NM_033071.3) | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV55124429; called by muse, mutect2
- SYNE2 | c.13914C>A p.Y4638* | Nonsense Mutation (SNP) | VAF 6/109 reads (6%) | catalogued as COSV59973238; called by muse, mutect2
- SYT7 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55660092; called by muse, mutect2
- TECPR2 | c.3155C>T p.T1052I | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63969321; called by muse, mutect2
- TLR9 | c.880A>T p.S294C | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62348758; called by muse, mutect2
- TMEM184C | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1056354158, COSV56855237; called by muse, mutect2
- TOM1L1 | c.33C>G p.Y11* | Nonsense Mutation (SNP) | VAF 10/165 reads (6%) | catalogued as COSV61949834; called by muse, mutect2
- TOP3A | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs750514439, COSV58174913; called by muse, mutect2, varscan2
- TRIOBP | c.3539A>G p.Q1180R | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV60385507; called by muse, mutect2
- TTC14 | c.1086A>T p.E362D | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV56014648; called by muse, mutect2
- TTN | c.40984A>G p.R13662G (on ENST00000591111; = p.R6238G on NM_003319.4) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | PolyPhen probably damaging (0.996); catalogued as COSV60397795; called by muse, mutect2
- UBQLNL | c.385A>G p.K129E | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV66494780; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2963G>C p.G988A | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV54443475; called by muse, mutect2, varscan2
- VPS13B | c.3967A>T p.S1323C | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62159921; called by muse, mutect2
- VSTM2L | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868797851, COSV65096265; called by muse, mutect2, varscan2
- ZBBX | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV56800488, COSV56803338; called by muse, mutect2
- ZC3H13 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs764357449, COSV54465156; called by muse, mutect2
- ZIC4 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as COSV67174408; called by muse, varscan2
- ZNF263 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373512796; called by muse, mutect2, varscan2
- ZRANB2 | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV54674933; called by muse, mutect2
- EIF4H | c.299_300del p.T100Ifs*23 | Frame Shift Del (DEL) | VAF 21/203 reads (10%) | called by mutect2, pindel, varscan2
- TP53 | c.542_543del p.R181Lfs*4 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by pindel, varscan2
- AHNAK2 | c.5808A>G p.K1936= | Silent (SNP) | VAF 21/435 reads (5%) | catalogued as COSV60933440; called by muse, mutect2
- ANK2 | c.7329A>G p.L2443= | Silent (SNP) | VAF 11/187 reads (6%) | catalogued as rs1346603121, COSV52193135; called by muse, mutect2
- ASZ1 | c.1236G>A p.L412= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV52916965; called by muse, mutect2
- CD1C | c.960G>T p.V320= | Silent (SNP) | VAF 31/614 reads (5%) | catalogued as rs1169277959, COSV63807878; called by muse, mutect2
- CD8B | c.234G>A p.G78= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs1342745930, COSV58928884; called by muse, mutect2
- COL4A1 | c.348G>A p.P116= | Silent (SNP) | VAF 47/448 reads (10%) | catalogued as rs760602242, COSV65423286; called by muse, mutect2, varscan2
- DNAH5 | c.13548A>G p.E4516= | Silent (SNP) | VAF 23/456 reads (5%) | catalogued as COSV54256988; called by muse, mutect2
- FAT4 | c.3822C>T p.D1274= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as COSV67902512; called by muse, mutect2
- GAB4 | c.1632G>A p.V544= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV68755397; called by muse, mutect2
- GABRA3 | c.1359C>T p.S453= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as COSV64806364; called by muse, mutect2, varscan2
- GCC2 | c.708T>C p.S236= | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as COSV59180563; called by muse, mutect2
- GRM4 | c.1626C>T p.C542= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs758454758, COSV65216138, COSV65216815; called by muse, mutect2, varscan2
- GTPBP1 | c.1083G>T p.P361= | Silent (SNP) | VAF 32/322 reads (10%) | catalogued as COSV53288324; called by muse, mutect2
- H1-3 | c.198G>A p.A66= | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as rs747596738, COSV55097044, COSV55098747; called by muse, mutect2
- HTR3E | c.465C>A p.P155= (on ENST00000415389 / NM_001256613.1; = p.P170= on NM_182589.2) | Silent (SNP) | VAF 31/392 reads (8%) | catalogued as COSV58949296; called by muse, mutect2
- INMT | c.108G>A p.E36= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as COSV50003102; called by muse, mutect2, varscan2
- KIF5B | c.1296T>G p.L432= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV56656769; called by muse, mutect2
- KRT5 | c.108C>G p.S36= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV52863958; called by muse, varscan2
- LAMP3 | c.1170C>A p.I390= | Silent (SNP) | VAF 39/556 reads (7%) | catalogued as rs1437426997, COSV55617253; called by muse, mutect2
- NBEA | c.5826G>T p.L1942= | Silent (SNP) | VAF 45/375 reads (12%) | catalogued as COSV100080619, COSV59829142; called by muse, mutect2, varscan2
- NLRP8 | c.2466A>C p.I822= | Silent (SNP) | VAF 32/351 reads (9%) | catalogued as COSV52595057; called by muse, mutect2
- NPHS1 | c.2200C>T p.L734= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1568453868, COSV62290212; called by muse, mutect2, varscan2
- PNPLA5 | c.513G>T p.L171= | Silent (SNP) | VAF 16/259 reads (6%) | catalogued as COSV53376564; called by muse, mutect2
- POTEF | c.339C>T p.S113= | Silent (SNP) | VAF 12/100 reads (12%) | called by mutect2, varscan2
- RBBP8 | c.1719A>G p.P573= | Silent (SNP) | VAF 24/209 reads (11%) | catalogued as rs1370981835, COSV59096509; called by muse, mutect2, varscan2
- SLC16A6 | c.585C>A p.I195= | Silent (SNP) | VAF 43/191 reads (23%) | catalogued as COSV59179322, COSV59179753; called by muse, mutect2, varscan2
- SLCO5A1 | c.1479A>C p.I493= | Silent (SNP) | VAF 18/239 reads (8%) | catalogued as COSV52662771, COSV52669638; called by muse, mutect2
- UBR4 | c.8352T>C p.N2784= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as COSV64401721; called by muse, mutect2
- XIRP1 | c.3360C>T p.V1120= | Silent (SNP) | VAF 14/238 reads (6%) | catalogued as COSV61141844; called by muse, mutect2
- ATP6V1D | c.*1T>A | 3'UTR (SNP) | VAF 21/362 reads (6%) | catalogued as COSV99370774; called by muse, mutect2
- DCHS2 | n.4740C>T | RNA (SNP) | VAF 14/209 reads (7%) | catalogued as COSV100601357, COSV61772559; called by muse, mutect2
- ERCC6 | c.1397+8320G>A | Intron (SNP) | VAF 38/524 reads (7%) | catalogued as COSV100875951, COSV63394978; called by muse, mutect2
